Somatic mutation profile of tumor specimen BA2470D (aliquot aq-BA2470D) from BEATAML1.0 case 2202, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.6 years (22,871 days).
Specimen BA2470D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e286529-7b7e-4a14-8264-db713972a450.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2010D (Solid Tissue Normal), aliquot aq-BA2010D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2fb6f711-600d-4822-9aa9-4683c91343d8

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 147/380 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LILRB4 | c.1127C>G p.P376R (on ENST00000391733 / NM_001278428.3; = p.P375R on NM_001278426.3) | Missense Mutation (SNP) | VAF 19/524 reads (4%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.931); called by muse, mutect2
- WDR7 | c.2083G>T p.V695L | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- DSC3 | c.915C>T p.T305= | Silent (SNP) | VAF 44/129 reads (34%) | called by muse, mutect2, varscan2
